Somatic mutation profile of tumor specimen TCGA-QR-A6H2-01A (aliquot TCGA-QR-A6H2-01A-11D-A35D-08) from TCGA case TCGA-QR-A6H2, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 33.6 years (12,281 days).
Specimen TCGA-QR-A6H2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17e6a09d-c4b9-4218-8676-627be0682cf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6H2-10A (Blood Derived Normal), aliquot TCGA-QR-A6H2-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74beaf78-73bf-4ae3-a5ea-7b7e2a83771b

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MINDY3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as rs760475633; called by muse, mutect2, varscan2
- ZNF519 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV101645594; called by muse, mutect2, varscan2
- MEPE | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MORN4 | c.379T>G p.C127G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2
